Somatic mutation profile of tumor specimen TCGA-J4-8200-01A (aliquot TCGA-J4-8200-01A-11D-A29Q-08) from TCGA case TCGA-J4-8200, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.0 years (17,167 days).
Specimen TCGA-J4-8200-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9214de83-2288-4b06-85b5-b34d796cd06c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-8200-10A (Blood Derived Normal), aliquot TCGA-J4-8200-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b93101d-447d-45d4-b215-090b48e56391

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 3, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 40/120 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs190140598, CM023669, COSV63663215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADORA2A | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs776505597, COSV58377935; called by mutect2, varscan2
- BBOX1 | c.101T>A p.L34* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV54189273; called by muse, mutect2, varscan2
- CNTN6 | c.1423G>T p.G475* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs1324149263, COSV63162444; called by muse, mutect2, varscan2
- DIRAS3 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63970464; called by muse, mutect2, varscan2
- GPR132 | c.406A>T p.I136F | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61677577; called by muse, mutect2, varscan2
- HECTD4 | c.8680C>T p.R2894W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748067375, COSV66386831; called by muse, mutect2, varscan2
- SH2B3 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57981306; called by muse, mutect2, varscan2
- SLFN11 | c.2502G>T p.R834S | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV57697597; called by muse, mutect2
- SRRM5 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1468083036, COSV56192634; called by muse, mutect2, varscan2
- TUSC1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as rs748273753, COSV63661420; called by muse, mutect2
- ST8SIA4 | c.357dup p.I120Hfs*4 | Frame Shift Ins (INS) | VAF 20/152 reads (13%) | called by pindel, varscan2
- USP28 | c.1891_1892insTTC p.E630_R631insI | In Frame Ins (INS) | VAF 10/106 reads (9%) | called by mutect2, pindel*
- ANKRD26 | c.558A>T p.A186= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV63091808; called by muse, varscan2
- NPHS2 | c.549C>T p.D183= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV62634611, COSV62637002; called by muse, mutect2, varscan2
- TXNDC16 | c.1515G>C p.S505= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV55983249, COSV55984169; called by muse, mutect2
